Somatic mutation profile of tumor specimen TCGA-D3-A8GC-06A (aliquot TCGA-D3-A8GC-06A-11D-A372-08) from TCGA case TCGA-D3-A8GC, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 53.2 years (19,418 days).
Specimen TCGA-D3-A8GC-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8abebbbf-51e1-46de-aa27-2d64cacb247e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A8GC-10A (Blood Derived Normal), aliquot TCGA-D3-A8GC-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9c8505b-fac0-4764-94da-40d2fcaecd3a

The open-access MAF lists 1,015 somatic variants for this specimen: 650 protein-altering or splice-affecting, 338 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 590, Silent 338, Nonsense Mutation 35, Splice Region 12, Intron 11, RNA 6, Frame Shift Del 5, Splice Site 4, 3'UTR 4, 5'Flank 3, Translation Start Site 2, 5'UTR 2.

Variants (750 of 1,015; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.1792C>T p.R598* | Nonsense Mutation (SNP) | VAF 102/128 reads (80%) | catalogued as rs139328569, CM050968; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CAV3 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs116840786, CM023343, COSV100664314, COSV100664380; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 138/155 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RPGRIP1 | c.2398G>A p.E800K | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as rs565837539, CM1312225, COSV52845281; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 102/159 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV99256848; called by muse, mutect2, varscan2
- ABCA3 | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100068775; called by muse, mutect2, varscan2
- ABCB5 | c.1705A>C p.K569Q (on ENST00000404938 / NM_001163941.2; = p.K124Q on NM_178559.6) | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV51720874; called by muse, mutect2
- ABCB5 | c.3598A>G p.K1200E (on ENST00000404938 / NM_001163941.2; = p.K755E on NM_178559.6) | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV99328815; called by muse, mutect2, varscan2
- ACACB | c.4810C>T p.P1604S | Missense Mutation (SNP) | VAF 38/46 reads (83%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV100623072; called by muse, mutect2, varscan2
- ACOX1 | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 84/181 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as COSV99503726; called by muse, mutect2, varscan2
- ACSM2B | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 70/293 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.162); catalogued as COSV100312876; called by muse, mutect2, varscan2
- ACSM3 | c.1675G>A p.V559I | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0.047); catalogued as COSV55502654; called by muse, mutect2, varscan2
- ACTG2 | c.908G>A p.G303D | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV100609290; called by muse, mutect2, varscan2
- ACTL7B | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 131/147 reads (89%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.981); catalogued as COSV65927419; called by muse, mutect2, varscan2
- ACVR1C | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs769612302, COSV54644545; called by muse, mutect2, varscan2
- ADAM18 | c.1970T>G p.F657C | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.095); catalogued as COSV99695820; called by muse, mutect2, varscan2
- ADAM29 | c.1049C>T p.S350L | Missense Mutation (SNP) | VAF 82/102 reads (80%) | SIFT deleterious (0.05); PolyPhen benign (0.342); catalogued as COSV100822084; called by muse, mutect2, varscan2
- ADAM32 | c.2215G>T p.G739C | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV65952645; called by muse, mutect2, varscan2
- ADAMDEC1 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99836143; called by muse, mutect2, varscan2
- ADAMTS5 | c.2482G>A p.E828K | Missense Mutation (SNP) | VAF 115/133 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99537889; called by muse, mutect2, varscan2
- ADGRV1 | c.13006G>A p.E4336K | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV101316152; called by muse, mutect2, varscan2
- AGAP4 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101432596; called by mutect2, varscan2
- AHNAK | c.12887C>T p.P4296L | Missense Mutation (SNP) | VAF 143/180 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99948215; called by muse, mutect2, varscan2
- AHNAK2 | c.8894C>T p.S2965F | Missense Mutation (SNP) | VAF 254/326 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as rs774461079, COSV100318094; called by muse, mutect2, varscan2
- AKAP3 | c.2332C>T p.Q778* | Nonsense Mutation (SNP) | VAF 36/106 reads (34%) | catalogued as COSV99962309; called by muse, mutect2, varscan2
- AKT1 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as COSV62574319; called by muse, mutect2, varscan2
- AL121899.2 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as COSV67352189; called by muse, mutect2, varscan2
- ALG10B | c.304C>T p.L102F | Missense Mutation (SNP) | VAF 60/81 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV58142810; called by muse, mutect2, varscan2
- ALOX5 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.496); catalogued as rs774166690, COSV100980100; called by muse, mutect2, varscan2
- ANGPTL2 | c.1348G>A p.G450R | Missense Mutation (SNP) | VAF 108/120 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99401936; called by muse, mutect2, varscan2
- ANK3 | c.9182C>T p.P3061L | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.994); catalogued as COSV99780741; called by muse, mutect2, varscan2
- ANK3 | c.5145A>T p.L1715F | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.66); catalogued as COSV99780742; called by muse, mutect2, varscan2
- ANK3 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs267602542, COSV55046002, COSV99777574; called by muse, mutect2, varscan2
- ANK3 | c.595G>T p.G199* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | catalogued as COSV99780747, COSV99781189; called by muse, mutect2, varscan2
- ANKRD30A | c.1168G>T p.D390Y (on ENST00000611781; = p.D334Y on NM_052997.2) | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.861); catalogued as COSV100653855; called by muse, mutect2, varscan2
- ANKRD30A | c.2146A>T p.K716* (on ENST00000611781; = p.K660* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 8/13 reads (62%) | catalogued as COSV100653857; called by mutect2, varscan2
- AOC1 | c.1493G>A p.G498D | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1268238024, COSV100710841; called by muse, mutect2, varscan2
- APBB1IP | c.534C>T p.L178= | Splice Region (SNP) | VAF 14/45 reads (31%) | catalogued as rs143340134; called by muse, mutect2, varscan2
- APC | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.059); catalogued as COSV99968645; called by muse, mutect2, varscan2
- APOH | c.437C>T p.S146F | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs1230677675, COSV52774770, COSV52775239; called by muse, mutect2
- APOL6 | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 146/153 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101291000; called by muse, mutect2, varscan2
- ARG1 | c.666-2A>C p.X222_splice | Splice Site (SNP) | VAF 121/142 reads (85%) | catalogued as CS165238, COSV99256152; called by muse, mutect2, varscan2
- ARGFX | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as COSV57681597, COSV57682310; called by muse, mutect2, varscan2
- ARHGEF17 | c.2684C>T p.P895L | Missense Mutation (SNP) | VAF 40/53 reads (75%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs772093395, COSV99736027; called by muse, mutect2, varscan2
- ARHGEF28 | c.2741G>A p.R914Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1032784486, COSV55254804, COSV99708932; called by muse, mutect2, varscan2
- ARHGEF35 | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.259); catalogued as COSV100967763; called by muse, mutect2, varscan2
- ASH1L | c.5659C>A p.H1887N | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.025); catalogued as COSV100853489; called by muse, mutect2, varscan2
- ASXL3 | c.3050C>T p.S1017F | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52480980; called by muse, mutect2, varscan2
- ATP13A5 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as rs372925735; called by muse, mutect2, varscan2
- ATP1A3 | c.1486C>T p.H496Y (on ENST00000545399 / NM_001256214.2; = p.H483Y on NM_152296.5) | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV100132364; called by muse, mutect2, varscan2
- ATP6V1C2 | c.130G>A p.V44M | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99695908; called by muse, mutect2, varscan2
- ATP8B3 | c.3817G>A p.G1273R | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.024); catalogued as COSV100034629; called by muse, mutect2, varscan2
- ATP8B3 | c.3691G>A p.E1231K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.091); catalogued as rs1328262095, COSV59547253; called by muse, mutect2
- ATXN2L | c.2521C>T p.Q841* | Nonsense Mutation (SNP) | VAF 59/134 reads (44%) | catalogued as COSV100294657; called by muse, mutect2, varscan2
- AVL9 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758275867, COSV100594672; called by muse, mutect2, varscan2
- B3GNT3 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100427523; called by muse, mutect2, varscan2
- BAZ2B | c.2524G>T p.E842* | Nonsense Mutation (SNP) | VAF 32/85 reads (38%) | catalogued as COSV100600785; called by muse, mutect2, varscan2
- BCAS3 | c.2582G>A p.R861Q (on ENST00000390652 / NM_001353144.2; = p.R846Q on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as rs768357672, COSV66775969; called by muse, mutect2, varscan2
- BIRC6 | c.10370T>C p.V3457A | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV101428434; called by muse, mutect2, varscan2
- BMP5 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 71/83 reads (86%) | SIFT tolerated (0.4); PolyPhen benign (0.041); catalogued as rs868777976, COSV63703310; called by muse, mutect2, varscan2
- BNIP5 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 70/83 reads (84%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV101465176; called by muse, mutect2, varscan2
- BRD1 | c.2825C>T p.S942F (on ENST00000216267 / NM_001349940.1; = p.S1073F on NM_001304808.3) | Missense Mutation (SNP) | VAF 52/63 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53460785; called by muse, mutect2, varscan2
- BRINP2 | c.37C>T p.R13W | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs200249029; called by muse, mutect2, varscan2
- BRINP2 | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100838173; called by muse, mutect2, varscan2
- C17orf97 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 17/18 reads (94%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV100789362; called by muse, mutect2, varscan2
- C2orf78 | c.2306G>A p.R769Q | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs375008239; called by muse, mutect2, varscan2
- C3 | c.3425C>T p.A1142V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as rs1244994133, COSV99836871; called by muse, mutect2, varscan2
- C7 | c.2285G>A p.S762N | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100495400, COSV100496074; called by muse, mutect2, varscan2
- C8A | c.1310A>G p.N437S | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.99); PolyPhen benign (0.005); catalogued as rs977066937, COSV100776564; called by muse, mutect2, varscan2
- C8orf34 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61389975; called by muse, mutect2, varscan2
- C8orf74 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV100262162; called by muse, mutect2, varscan2
- C9 | c.560G>A p.G187E | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV99662202; called by muse, mutect2, varscan2
- CAPN15 | c.2028C>A p.D676E | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761049457, COSV54834924, COSV99562583; called by muse, mutect2, varscan2
- CAPN15 | c.2029C>T p.L677F | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1340202502, COSV99562584; called by muse, mutect2, varscan2
- CAPN7 | c.216_219del p.S73Rfs*6 | Frame Shift Del (DEL) | VAF 15/43 reads (35%) | catalogued as rs1231338873; called by mutect2, pindel, varscan2
- CAPZA3 | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV56848576; called by muse, mutect2, varscan2
- CASR | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT tolerated (1); PolyPhen possibly damaging (0.583); catalogued as COSV56136452; called by muse, mutect2, varscan2
- CCDC141 | c.3496C>T p.L1166F | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV99837037; called by muse, mutect2, varscan2
- CCDC171 | c.2860G>C p.A954P | Missense Mutation (SNP) | VAF 53/56 reads (95%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99901179; called by muse, mutect2, varscan2
- CCDC198 | c.523C>T p.H175Y | Missense Mutation (SNP) | VAF 55/66 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV99371292; called by muse, mutect2, varscan2
- CCDC54 | c.776G>A p.W259* | Nonsense Mutation (SNP) | VAF 50/113 reads (44%) | catalogued as COSV99660177, COSV99660251; called by muse, mutect2, varscan2
- CCN4 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs560735095, COSV51530894, COSV99137203; called by muse, mutect2, varscan2
- CDC42EP4 | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100231881; called by muse, mutect2, varscan2
- CDCP1 | c.2082G>A p.K694= | Splice Region (SNP) | VAF 60/155 reads (39%) | catalogued as rs1444437435, COSV56108204; called by muse, mutect2, varscan2
- CDCP1 | c.1248C>T p.S416= | Splice Region (SNP) | VAF 69/184 reads (38%) | catalogued as COSV99944145; called by muse, mutect2, varscan2
- CDH12 | c.490C>A p.P164T | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV101202833; called by muse, mutect2, varscan2
- CDH13 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 58/72 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99221744, COSV99227491; called by muse, mutect2, varscan2
- CDH17 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99217619; called by muse, mutect2, varscan2
- CDH4 | c.2581C>T p.P861S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100849205; called by muse, mutect2, varscan2
- CDH6 | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.595); catalogued as rs762454450, COSV99417803; called by muse, mutect2, varscan2
- CDHR1 | c.1225G>A p.V409I | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV60565994; called by muse, mutect2, varscan2
- CDYL2 | c.1138C>T p.Q380* | Nonsense Mutation (SNP) | VAF 65/111 reads (59%) | catalogued as COSV101629593; called by muse, mutect2, varscan2
- CEP120 | c.1423A>G p.I475V | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs778311900, COSV100071230; called by muse, mutect2, varscan2
- CEP170 | c.14C>T p.S5F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100839767; called by muse, mutect2, varscan2
- CERS3 | c.1076G>A p.G359D | Missense Mutation (SNP) | VAF 16/17 reads (94%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1477105561, COSV99432280; called by muse, mutect2, varscan2
- CFAP221 | c.1957G>A p.D653N | Missense Mutation (SNP) | VAF 93/204 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0.01); catalogued as COSV54661801; called by muse, mutect2, varscan2
- CHAF1A | c.2459T>A p.V820E | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100011315; called by muse, mutect2, varscan2
- CHD4 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs754152386, COSV100537253; called by muse, mutect2, varscan2
- CHGB | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV100972999; called by muse, mutect2, varscan2
- CHL1 | c.2257C>T p.P753S (on ENST00000397491 / NM_001253387.1; = p.P769S on NM_006614.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.355); catalogued as rs1306391833, COSV99850781; called by muse, mutect2
- CLASRP | c.1642C>T p.P548S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.986); catalogued as rs771355999, COSV99673944; called by muse, mutect2, varscan2
- CLEC10A | c.758G>A p.G253E (on ENST00000254868 / NM_182906.4; = p.G229E on NM_006344.4) | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1471199418, COSV99644704; called by muse, mutect2, varscan2
- CLEC10A | c.555G>A p.W185* (on ENST00000254868 / NM_182906.4; = p.W161* on NM_006344.4) | Nonsense Mutation (SNP) | VAF 33/46 reads (72%) | catalogued as COSV99644766, COSV99645026; called by muse, mutect2, varscan2
- CLSTN2 | c.2708G>A p.G903E | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754087978, COSV101515830; called by muse, mutect2, varscan2
- CNTN5 | c.1222C>T p.R408* | Nonsense Mutation (SNP) | VAF 17/19 reads (89%) | catalogued as rs771353785, COSV99676130; called by muse, mutect2, varscan2
- CNTNAP2 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 73/175 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV62143246; called by muse, mutect2, varscan2
- CNTNAP4 | c.2797C>T p.R933W | Missense Mutation (SNP) | VAF 72/133 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1450320927, COSV56678851, COSV56703566; called by muse, mutect2, varscan2
- CNTNAP4 | c.3023C>T p.S1008L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs1210707564, COSV100272139; called by muse, mutect2, varscan2
- COCH | c.1291G>C p.V431L (on ENST00000216361 / NM_001347720.1; = p.V366L on NM_004086.3) | Missense Mutation (SNP) | VAF 50/63 reads (79%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.84); catalogued as COSV99363727; called by muse, mutect2, varscan2
- COL14A1 | c.2440G>A p.D814N | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV99919741; called by muse, mutect2, varscan2
- COL1A2 | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV51967877; called by muse, mutect2, varscan2
- COL20A1 | c.1191G>A p.W397* | Nonsense Mutation (SNP) | VAF 14/31 reads (45%) | catalogued as COSV58912115; called by muse, mutect2, varscan2
- COL22A1 | c.3746G>A p.G1249E | Missense Mutation (SNP) | VAF 121/214 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100279111; called by muse, mutect2, varscan2
- COL23A1 | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768592831, COSV101179237; called by muse, mutect2, varscan2
- COL24A1 | c.3934G>A p.G1312R | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750292545, COSV100993555; called by muse, mutect2, varscan2
- COL24A1 | c.3176G>A p.G1059E | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs533684198, COSV65317534; called by muse, mutect2, varscan2
- COL2A1 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 100/123 reads (81%) | SIFT tolerated (0.5); PolyPhen benign (0.245); catalogued as COSV61528716; called by muse, mutect2, varscan2
- COL4A4 | c.1661G>A p.G554E | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100306418; called by muse, mutect2, varscan2
- COL4A5 | c.1405G>A p.G469R | Missense Mutation (SNP) | VAF 43/50 reads (86%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV100087360, COSV100088384; called by muse, mutect2, varscan2
- COL5A1 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 60/75 reads (80%) | SIFT tolerated (0.63); PolyPhen benign (0.245); catalogued as COSV65672129; called by muse, mutect2, varscan2
- COL5A1 | c.4903C>T p.P1635S | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100880126; called by muse, mutect2, varscan2
- COL6A6 | c.2756C>T p.T919I | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100650478; called by muse, mutect2, varscan2
- COL9A2 | c.793G>A p.G265S | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101025727; called by muse, mutect2, varscan2
- COL9A2 | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756445062, COSV101025729; called by muse, mutect2, varscan2
- CRIM1 | c.1643G>T p.C548F | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1331718952, COSV99753755; called by muse, mutect2, varscan2
- CRLF3 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs546555105, COSV100158452; called by muse, mutect2, varscan2
- CSF1 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 56/65 reads (86%) | SIFT tolerated (0.4); PolyPhen benign (0.138); catalogued as COSV60033627; called by muse, mutect2
- CSF1 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 58/68 reads (85%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV100294681; called by muse, mutect2
- CSMD1 | c.8707G>A p.D2903N (on ENST00000520002; = p.D2902N on NM_033225.6) | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.914); catalogued as COSV59321665; called by muse, mutect2, varscan2
- CSMD3 | c.10052C>T p.S3351F (on ENST00000297405 / NM_001363185.1; = p.S3182F on NM_052900.3) | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as rs1310279550, COSV52137625, COSV99838503; called by muse, mutect2, varscan2
- CSMD3 | c.3425C>T p.P1142L (on ENST00000297405 / NM_001363185.1; = p.P1038L on NM_052900.3) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52213805, COSV99838507; called by muse, mutect2, varscan2
- CSMD3 | c.3424C>T p.P1142S (on ENST00000297405 / NM_001363185.1; = p.P1038S on NM_052900.3) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99838509; called by muse, mutect2, varscan2
- CTCFL | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.575); catalogued as COSV99712972; called by muse, mutect2, varscan2
- CXCR1 | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV99826366; called by muse, mutect2, varscan2
- CYLC1 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 22/25 reads (88%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV61411400, COSV61413609; called by muse, mutect2, varscan2
- CYP11A1 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 50/61 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99166064; called by muse, mutect2, varscan2
- CYP2C8 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762895826, COSV100987959; called by muse, mutect2, varscan2
- CYP2C8 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.158); catalogued as COSV64877499; called by muse, mutect2, varscan2
- CYP3A7 | c.1154G>A p.G385E | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs375588438, COSV100312722; called by muse, mutect2, varscan2
- CYP4F12 | c.1385C>T p.S462F | Missense Mutation (SNP) | VAF 80/155 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs374175073; called by muse, mutect2, varscan2
- CYP4F22 | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV54110418, COSV99512905; called by muse, mutect2, varscan2
- CYP4F3 | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as rs1015611972, COSV55414174; called by muse, mutect2, varscan2
- DAB1 | c.878C>T p.S293F (on ENST00000371231; = p.S260F on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100976133, COSV64689897; called by muse, mutect2, varscan2
- DACT1 | c.1379C>T p.S460L | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as rs760704027, COSV100241944; called by muse, mutect2, varscan2
- DCLK3 | c.285G>A p.W95* | Nonsense Mutation (SNP) | VAF 68/163 reads (42%) | catalogued as COSV101374015; called by muse, mutect2, varscan2
- DDX23 | c.1427C>T p.P476L | Missense Mutation (SNP) | VAF 49/61 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100339892; called by muse, mutect2, varscan2
- DHX34 | c.2122A>T p.S708C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100169702; called by muse, mutect2
- DHX9 | c.3614C>T p.S1205F | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as COSV62358968; called by muse, mutect2, varscan2
- DIAPH2 | c.1846C>T p.P616S | Missense Mutation (SNP) | VAF 28/30 reads (93%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100233594; called by muse, mutect2, varscan2
- DKK2 | c.314G>A p.R105K | Missense Mutation (SNP) | VAF 48/57 reads (84%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.973); catalogued as COSV99569116; called by muse, mutect2, varscan2
- DLGAP4 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV100211409; called by muse, mutect2, varscan2
- DMBT1 | c.659C>T p.S220L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0.054); catalogued as rs1448890586; called by muse, mutect2
- DMGDH | c.2182G>A p.G728R | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99669184; called by muse, mutect2, varscan2
- DNAH1 | c.3532C>T p.P1178S | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.086); catalogued as rs1348961156, COSV101326346; called by muse, mutect2, varscan2
- DNAH17 | c.4460C>T p.S1487F | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.657); catalogued as COSV101102743; called by muse, varscan2
- DNAH3 | c.10168G>C p.E3390Q | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.432); catalogued as COSV54505260, COSV99768584; called by muse, mutect2, varscan2
- DNAH3 | c.7040T>C p.L2347S | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99768593; called by muse, mutect2, varscan2
- DNAH5 | c.10802C>T p.P3601L | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54218063; called by muse, mutect2, varscan2
- DNAH5 | c.10801C>T p.P3601S | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1158803420, COSV99451289; called by muse, mutect2, varscan2
- DNAH5 | c.5105C>T p.S1702F | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs542591554, COSV54202517; called by muse, mutect2, varscan2
- DNAH5 | c.4529G>A p.G1510E | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99451292; called by muse, mutect2, varscan2
- DNAH5 | c.3754G>A p.D1252N | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV99451294; called by muse, mutect2, varscan2
- DNAH5 | c.2406T>A p.Y802* | Nonsense Mutation (SNP) | VAF 31/77 reads (40%) | catalogued as COSV99451298; called by muse, mutect2, varscan2
- DNAH8 | c.11604G>A p.W3868* | Nonsense Mutation (SNP) | VAF 108/128 reads (84%) | catalogued as COSV100546096; called by muse, mutect2
- DNAJA3 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs1232524915, COSV52164140; called by muse, mutect2, varscan2
- DOCK3 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV56514475; called by muse, mutect2, varscan2
- DOCK3 | c.3293C>T p.P1098L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV56554929; called by muse, mutect2, varscan2
- DOCK4 | c.5236G>A p.A1746T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs773731165, COSV101447898; called by muse, mutect2, varscan2
- DOCK4 | c.978G>A p.M326I | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs200828913, COSV101455605; called by muse, mutect2, varscan2
- DPYD | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 74/90 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64612983, COSV64613125, COSV64615120; called by muse, mutect2, varscan2
- DPYSL5 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV99982510; called by muse, mutect2, varscan2
- DRGX | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 51/85 reads (60%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100938356, COSV65136146; called by muse, mutect2, varscan2
- DSG1 | c.2455G>A p.G819S | Missense Mutation (SNP) | VAF 60/79 reads (76%) | SIFT tolerated (0.37); PolyPhen benign (0.035); catalogued as COSV99936200; called by muse, mutect2, varscan2
- DYSF | c.4966G>A p.D1656N | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV50460162; called by muse, mutect2, varscan2
- E2F8 | c.2003G>A p.R668K | Missense Mutation (SNP) | VAF 81/92 reads (88%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV51464574; called by muse, mutect2, varscan2
- E2F8 | c.556C>T p.L186F | Missense Mutation (SNP) | VAF 68/88 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100001582; called by muse, mutect2, varscan2
- EBF2 | c.317G>A p.G106D | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765517076, COSV101282234; called by muse, mutect2, varscan2
- ECEL1 | c.1382A>C p.H461P | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.899); catalogued as COSV100458817; called by muse, mutect2, varscan2
- EDN3 | c.688C>T p.R230C (on ENST00000337938 / NM_001302455.2; = p.R216C on NM_207033.3) | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs372958987; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EFCAB13 | c.1516G>A p.G506R | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs967559742, COSV58951482; called by muse, mutect2, varscan2
- EFCAB13 | c.2446G>A p.D816N | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV58945967; called by muse, mutect2, varscan2
- EFCAB13 | c.2536G>A p.D846N | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.402); catalogued as COSV100516382; called by muse, mutect2, varscan2
- EFCAB3 | c.75G>A p.R25= | Splice Region (SNP) | VAF 32/106 reads (30%) | catalogued as rs1380004430, COSV100540005; called by muse, mutect2, varscan2
- EGFR | c.1340C>T p.S447F | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.993); catalogued as COSV51788608, COSV51822525; called by muse, mutect2, varscan2
- ELAVL2 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 117/129 reads (91%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); catalogued as COSV56359999; called by muse, mutect2, varscan2
- ELOVL1 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100196532; called by muse, mutect2, varscan2
- ELP2 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 38/53 reads (72%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV100626926; called by muse, mutect2, varscan2
- EPHA3 | c.1927C>T p.P643S | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV60722477; called by muse, mutect2, varscan2
- ESYT2 | c.1874C>T p.T625I (on ENST00000613624; = p.T549I on NM_020728.3) | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs745644547, COSV99276937; called by muse, mutect2, varscan2
- F11 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 30/38 reads (79%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs371437683, COSV99251651; called by muse, mutect2, varscan2
- F5 | c.4289C>T p.S1430F | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV100889157; called by muse, mutect2, varscan2
- FAM170A | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58925205; called by muse, mutect2, varscan2
- FAM193A | c.2014C>T p.P672S | Missense Mutation (SNP) | VAF 57/74 reads (77%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as rs1560576317, COSV100219348; called by muse, mutect2, varscan2
- FAM216B | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV100573068; called by muse, mutect2, varscan2
- FBXL13 | c.1514C>T p.P505L | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV100501810; called by muse, mutect2, varscan2
- FBXW4 | c.1277C>T p.P426L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs1419049262, COSV100489514; called by muse, mutect2, varscan2
- FCER1A | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); catalogued as COSV63666491; called by muse, mutect2, varscan2
- FCRL5 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs1194540594, COSV100709065; called by muse, mutect2, varscan2
- FER1L6 | c.2332G>A p.D778N | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs200539572, COSV101205991, COSV101206251; called by muse, mutect2, varscan2
- FGR | c.1457C>T p.S486F | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100925855, COSV64969832; called by muse, mutect2, varscan2
- FILIP1 | c.2755G>A p.E919K | Missense Mutation (SNP) | VAF 79/93 reads (85%) | SIFT tolerated (0.76); PolyPhen benign (0.048); catalogued as rs757733034, COSV52727424, COSV99385275; called by muse, mutect2, varscan2
- FLG | c.2524C>T p.R842C | Missense Mutation (SNP) | VAF 150/360 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as rs764114936, COSV64246869; called by muse, mutect2, varscan2
- FLG | c.365G>A p.R122K | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.88); PolyPhen benign (0.006); catalogued as COSV100911707; called by muse, mutect2, varscan2
- FLNB | c.7460C>T p.S2487F | Missense Mutation (SNP) | VAF 82/194 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs771879974, COSV99913790; called by muse, mutect2, varscan2
- FMN2 | c.2921G>A p.G974E | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.409); catalogued as rs768840625, COSV60421408; called by muse, mutect2, varscan2
- FNDC3B | c.2793C>T p.Y931= | Splice Region (SNP) | VAF 15/34 reads (44%) | catalogued as rs1465290061, COSV100394392; called by muse, mutect2, varscan2
- FNDC3B | c.2794C>T p.R932W | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs373434503, COSV100394394; called by muse, mutect2, varscan2
- FREM1 | c.1375G>A p.G459R | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100772197; called by muse, mutect2, varscan2
- FRMPD2 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV100563946; called by muse, mutect2, varscan2
- FRMPD2 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0.276); catalogued as COSV100563949; called by muse, mutect2, varscan2
- FRMPD4 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 35/38 reads (92%) | SIFT tolerated (0.15); PolyPhen benign (0.063); catalogued as COSV101043288; called by muse, mutect2, varscan2
- FRS3 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99442925; called by muse, mutect2, varscan2
- FSIP2 | c.17308G>A p.D5770N | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1479991993, COSV100555547; called by muse, mutect2, varscan2
- GABRB2 | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 48/85 reads (56%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs202183786, COSV50936354; ClinVar: benign; called by muse, mutect2, varscan2
- GALNT8 | c.764G>A p.R255K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as COSV99362971; called by muse, mutect2, varscan2
- GAS2L2 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as rs1555599005; called by muse, mutect2, varscan2
- GDPD4 | c.1369G>A p.D457N | Missense Mutation (SNP) | VAF 26/27 reads (96%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779034959, COSV100265400; called by muse, mutect2, varscan2
- GGN | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.258); catalogued as rs765395570, COSV99287533; called by muse, mutect2, varscan2
- GHR | c.1759G>A p.G587S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100051182, COSV50106292; called by muse, mutect2, varscan2
- GIMAP6 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as rs868377767, COSV100188306; called by muse, mutect2, varscan2
- GJB3 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.64); PolyPhen benign (0.05); catalogued as rs752713622, COSV100974025; called by muse, mutect2, varscan2
- GLIS1 | c.676G>A p.G226S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as rs773798489, COSV100390297; called by muse, mutect2, varscan2
- GPC6 | c.213G>A p.M71I | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as COSV65499160; called by muse, mutect2, varscan2
- GPNMB | c.338A>G p.N113S | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV99326580; called by muse, mutect2, varscan2
- GPR12 | c.532G>A p.G178S | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101197989, COSV101198018; called by muse, mutect2, varscan2
- GPR141 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.195); catalogued as rs749335333, COSV100550362; called by muse, mutect2, varscan2
- GPR27 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1355749342, COSV99816521; called by muse, mutect2, varscan2
- GPR52 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 95/205 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs138614960, COSV52335448; called by muse, mutect2, varscan2
- GPR78 | c.777G>A p.M259I | Missense Mutation (SNP) | VAF 46/63 reads (73%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101223999, COSV66763726; called by muse, mutect2, varscan2
- GRHL2 | c.89C>G p.T30S | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.348); catalogued as COSV99307272; called by muse, mutect2, varscan2
- GRIA2 | c.2639G>A p.S880N | Missense Mutation (SNP) | VAF 75/89 reads (84%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.351); catalogued as COSV99645021; called by muse, mutect2, varscan2
- GRIK2 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 20/22 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs1269034550, COSV59752057; called by muse, mutect2, varscan2
- GRIK3 | c.2755C>T p.P919S | Missense Mutation (SNP) | VAF 42/51 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs200512044, COSV100902147; called by muse, mutect2, varscan2
- GRIN2A | c.2030C>T p.S677F | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV58019302; called by muse, mutect2, varscan2
- GRM8 | c.1996C>T p.L666F | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100280815; called by muse, mutect2, varscan2
- GSG1L | c.672G>A p.W224* (on ENST00000447459 / NM_001109763.2; = p.W69* on NM_144675.2) | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV101093792; called by muse, mutect2, varscan2
- GYS2 | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV99679931; called by muse, mutect2, varscan2
- H2AC20 | c.107G>T p.R36L | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.622); catalogued as COSV100480021, COSV58611152; called by muse, mutect2, varscan2
- HDAC5 | c.571C>T p.L191F | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV56821864; called by muse, mutect2, varscan2
- HDAC9 | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as COSV101287226, COSV67781572; called by muse, mutect2, varscan2
- HEXD | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100027810; called by muse, mutect2, varscan2
- HHIPL2 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 107/249 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58564422; called by muse, mutect2, varscan2
- HIVEP2 | c.6730C>T p.L2244F | Missense Mutation (SNP) | VAF 49/59 reads (83%) | SIFT tolerated (0.07); PolyPhen benign (0.117); catalogued as rs372916482; called by muse, mutect2, varscan2
- HLA-DPA1 | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 41/50 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101343126; called by muse, mutect2, varscan2
- HOXA3 | c.1291C>T p.Q431* | Nonsense Mutation (SNP) | VAF 55/117 reads (47%) | catalogued as COSV100415539, COSV57828754; called by muse, mutect2, varscan2
- HOXD8 | c.706C>T p.L236F | Missense Mutation (SNP) | VAF 85/221 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1315057888, COSV100497119; called by muse, mutect2, varscan2
- HR | c.1262G>A p.G421E | Missense Mutation (SNP) | VAF 50/73 reads (68%) | SIFT tolerated (0.14); PolyPhen benign (0.101); catalogued as COSV100455923; called by muse, mutect2, varscan2
- HSPH1 | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 72/145 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV100185014; called by muse, mutect2, varscan2
- HTR5A | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99839458; called by muse, mutect2, varscan2
- IFIT1B | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as rs199669012, COSV65663250; called by muse, mutect2, varscan2
- IFNA4 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 129/147 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV101427028, COSV101427070; called by muse, mutect2, varscan2
- IGHV1-24 | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 99/129 reads (77%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.737); catalogued as rs374208649; called by muse, mutect2, varscan2
- IGHV3-23 | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 127/315 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.088); catalogued as rs376993805; called by muse, mutect2, varscan2
- IGSF1 | c.3898G>A p.D1300N | Missense Mutation (SNP) | VAF 56/66 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV100812173; called by muse, mutect2, varscan2
- IGSF1 | c.1391C>T p.S464L | Missense Mutation (SNP) | VAF 52/62 reads (84%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV100812174; called by muse, mutect2, varscan2
- IGSF21 | c.1028G>A p.G343E | Missense Mutation (SNP) | VAF 160/183 reads (87%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV52146825; called by muse, mutect2, varscan2
- IL18RAP | c.1018C>T p.Q340* | Nonsense Mutation (SNP) | VAF 17/51 reads (33%) | catalogued as COSV99962161; called by muse, mutect2, varscan2
- IL1R1 | c.1648C>T p.Q550* | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as COSV99292696; called by muse, mutect2, varscan2
- IL36A | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 37/77 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV99382157; called by muse, mutect2, varscan2
- IL36B | c.424C>T p.H142Y | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as COSV99382920; called by muse, mutect2, varscan2
- ING1 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.169); catalogued as rs1486590396, COSV58169223; called by muse, mutect2, varscan2
- ITGA3 | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as rs749405129, COSV99143802; called by muse, mutect2, varscan2
- ITGAE | c.1519G>A p.G507R | Missense Mutation (SNP) | VAF 24/27 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99561187; called by muse, mutect2, varscan2
- ITGAX | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99191860; called by muse, mutect2, varscan2
- ITIH5 | c.1780G>A p.D594N | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs150174865; called by muse, mutect2, varscan2
- ITLN2 | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1468883133, COSV100600730; called by muse, mutect2, varscan2
- JHY | c.1492G>T p.E498* | Nonsense Mutation (SNP) | VAF 75/84 reads (89%) | catalogued as COSV99912764, COSV99913810; called by muse, mutect2, varscan2
- JPH4 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1390664992, COSV100689333; called by muse, mutect2, varscan2
- KALRN | c.7367C>T p.T2456I (on ENST00000360013 / NM_001024660.4; = p.T759I on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.998); catalogued as COSV52267218, COSV99362388; called by muse, mutect2, varscan2
- KCNB1 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.814); catalogued as rs755481445, COSV100870504; called by muse, mutect2, varscan2
- KCNJ2 | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs1320510274, COSV54663289; called by muse, mutect2, varscan2
- KCNJ5 | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs746793322, COSV100610735; called by muse, mutect2, varscan2
- KCNMB4 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 66/79 reads (84%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV99253267; called by muse, mutect2, varscan2
- KCNQ3 | c.1928A>C p.H643P | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101196238; called by muse, mutect2, varscan2
- KCNQ3 | c.1927C>A p.H643N | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV101196239; called by muse, mutect2, varscan2
- KIF26B | c.2495C>T p.P832L | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1558269577, COSV100832793; called by muse, mutect2, varscan2
- KLHL14 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 49/57 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs935229084, COSV100839246; called by muse, mutect2, varscan2
- KLK6 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs867955682, COSV100037741; called by muse, mutect2, varscan2
- KMT2B | c.5720C>T p.P1907L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as rs1338908063, COSV99719949; called by muse, mutect2, varscan2
- KMT5A | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as rs1350271269, COSV100389545; called by mutect2, varscan2
- KMT5C | c.1352G>A p.G451D | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.295); catalogued as rs768571547, COSV99726232; called by muse, varscan2
- KPRP | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.472); catalogued as rs1174240097, COSV100908734; called by muse, mutect2, varscan2
- KRT37 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs535890482, COSV99845589; called by muse, mutect2, varscan2
- KRT85 | c.865G>A p.D289N | Missense Mutation (SNP) | VAF 37/48 reads (77%) | SIFT deleterious (0.05); PolyPhen benign (0.167); catalogued as COSV99225553; called by muse, mutect2, varscan2
- KRTAP17-1 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 6/14 reads (43%) | PolyPhen probably damaging (0.999); catalogued as rs749455809, COSV100498578; called by muse, mutect2, varscan2
- LAD1 | c.107A>G p.N36S | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.475); catalogued as COSV100943878; called by muse, mutect2, varscan2
- LDHD | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs1161744613, COSV100097232; called by muse, mutect2, varscan2
- LDHD | c.163G>A p.G55R | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs758475011, COSV100097235; called by muse, mutect2, varscan2
- LEMD1 | c.385G>A p.G129R (on ENST00000367151; = p.M81I on NM_001001552.5) | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100903473; called by muse, mutect2, varscan2
- LGR6 | c.355C>T p.L119= (on ENST00000367278 / NM_001017403.1; = p.L67= on NM_021636.3) | Splice Region (SNP) | VAF 27/68 reads (40%) | catalogued as COSV99707349; called by muse, mutect2, varscan2
- LHX6 | c.374+1G>A p.X125_splice (on ENST00000373755 / NM_001242334.2; = p.X154_splice on NM_014368.5) | Splice Site (SNP) | VAF 84/94 reads (89%) | catalogued as COSV100493505; called by muse, mutect2, varscan2
- LLGL2 | c.705C>A p.N235K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs1211391232, COSV99390036; called by muse, mutect2, varscan2
- LMOD2 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs371400622; called by muse, varscan2
- LPA | c.3461C>T p.S1154F | Missense Mutation (SNP) | VAF 127/144 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV100307338; called by muse, mutect2, varscan2
- LRP1B | c.9040G>A p.E3014K | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.156); catalogued as COSV101257967, COSV67247579; called by muse, mutect2, varscan2
- LRP1B | c.7762+1G>A p.X2588_splice | Splice Site (SNP) | VAF 56/115 reads (49%) | catalogued as COSV101257968; called by muse, mutect2, varscan2
- LRP1B | c.296G>A p.G99D | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV101257969; called by muse, mutect2, varscan2
- LRP6 | c.3911C>T p.A1304V | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.21); catalogued as COSV99743702; called by muse, mutect2, varscan2
- LRRC37A3 | c.4795C>T p.L1599F | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1273695187, COSV58534612; called by muse, mutect2, varscan2
- LRRC7 | c.697G>A p.E233K (on ENST00000651989 / NM_001370785.2; = p.E200K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV50651939; called by muse, mutect2, varscan2
- LRRIQ3 | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.738); catalogued as rs1176496452, COSV100598983, COSV63047582; called by muse, mutect2, varscan2
- LRRN1 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT tolerated (0.69); PolyPhen benign (0.428); catalogued as COSV100076412; called by muse, mutect2, varscan2
- LTBP1 | c.4705G>A p.D1569N (on ENST00000404816 / NM_206943.4; = p.D1243N on NM_000627.4) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.046); catalogued as COSV55378807; called by muse, mutect2, varscan2
- LYPD6 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100493610; called by muse, mutect2, varscan2
- LYZL2 | c.279G>A p.W93* (on ENST00000375318; = p.W47* on NM_183058.3) | Nonsense Mutation (SNP) | VAF 14/45 reads (31%) | catalogued as COSV100940613; called by muse, mutect2, varscan2
- LZTS3 | c.326C>T p.T109I | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0.067); catalogued as COSV100232325; called by muse, mutect2, varscan2
- MACF1 | c.20516C>T p.P6839L (on ENST00000372915; = p.P4884L on NM_012090.5) | Missense Mutation (SNP) | VAF 83/197 reads (42%) | catalogued as COSV99245448; called by muse, mutect2, varscan2
- MAGEA10 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 79/89 reads (89%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV54885180; called by muse, mutect2, varscan2
- MAGEA12 | c.58G>A p.G20R | Missense Mutation (SNP) | VAF 35/41 reads (85%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.791); catalogued as COSV63295641; called by muse, mutect2, varscan2
- MAGEC3 | c.1414C>T p.Q472* | Nonsense Mutation (SNP) | VAF 39/45 reads (87%) | catalogued as rs1210749310, COSV53575606; called by muse, mutect2, varscan2
- MAMLD1 | c.1433C>T p.S478F | Missense Mutation (SNP) | VAF 34/39 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV53380620; called by muse, mutect2, varscan2
- MAP3K13 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.655); catalogued as COSV53990840; called by muse, mutect2, varscan2
- MARVELD2 | c.57C>G p.S19R | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100347766, COSV57781500; called by muse, mutect2
- MAST2 | c.2131A>T p.M711L | Missense Mutation (SNP) | VAF 231/260 reads (89%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.475); catalogued as COSV100788427; called by muse, mutect2, varscan2
- MCC | c.1456C>T p.P486S | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs200525451, COSV100202869; called by muse, mutect2, varscan2
- MCEMP1 | c.148C>T p.H50Y | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs1568480773, COSV100365396; called by muse, mutect2, varscan2
- MED12L | c.2941G>A p.D981N | Missense Mutation (SNP) | VAF 96/196 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs1421729479, COSV99853732; called by muse, mutect2, varscan2
- MED26 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs771812981, COSV99660058; called by muse, mutect2, varscan2
- MEGF10 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as rs1302228290, COSV57255606; called by muse, varscan2
- MEST | c.353A>G p.Y118C | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as COSV99784333; called by muse, mutect2, varscan2
- MET | c.1958C>T p.S653F | Missense Mutation (SNP) | VAF 101/214 reads (47%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs1554395395, COSV100577279; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MFSD3 | c.1108A>T p.K370* | Nonsense Mutation (SNP) | VAF 25/71 reads (35%) | catalogued as COSV100020689; called by muse, mutect2, varscan2
- MKI67 | c.8459C>T p.T2820I | Missense Mutation (SNP) | VAF 66/100 reads (66%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.724); catalogued as COSV100896728; called by muse, mutect2, varscan2
- MLLT10 | c.1736C>T p.P579L (on ENST00000307729 / NM_001195626.3; = p.P595L on NM_004641.3) | Missense Mutation (SNP) | VAF 58/118 reads (49%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as COSV100308340; called by muse, mutect2, varscan2
- MMP13 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV99506671; called by muse, mutect2, varscan2
- MPP7 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.5); PolyPhen benign (0.179); catalogued as rs147738330; called by muse, mutect2, varscan2
- MROH2B | c.745C>T p.H249Y | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1374058264, COSV68185215; called by muse, mutect2, varscan2
- MSR1 | c.1175G>A p.G392E | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50530256; called by muse, mutect2, varscan2
- MSR1 | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs759789522, COSV100027550; called by muse, mutect2, varscan2
- MTMR4 | c.2960C>T p.P987L | Missense Mutation (SNP) | VAF 99/205 reads (48%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs559247649, COSV100051172; called by muse, mutect2, varscan2
- MTNR1B | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99925197; called by muse, mutect2, varscan2
- MUC16 | c.35293C>T p.P11765S | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.91); catalogued as rs746293537, COSV101199312; called by muse, mutect2, varscan2
- MUC16 | c.32243G>A p.R10748K | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.009); catalogued as COSV101200332; called by muse, mutect2, varscan2
- MUC16 | c.22763C>T p.S7588L | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.205); catalogued as COSV101200333; called by muse, mutect2, varscan2
- MUC16 | c.18215C>T p.S6072F | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs1399683477, COSV101200334; called by muse, mutect2, varscan2
- MUC16 | c.16340C>T p.S5447L | Missense Mutation (SNP) | VAF 97/214 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.276); catalogued as rs756902744, COSV67455338; called by muse, mutect2, varscan2
- MUC16 | c.13908G>A p.M4636I | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV101200335; called by muse, mutect2, varscan2
- MUC16 | c.11663C>T p.S3888F | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); catalogued as COSV67492452; called by muse, mutect2, varscan2
- MUC16 | c.10069G>A p.D3357N | Missense Mutation (SNP) | VAF 77/173 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); catalogued as rs750851294, COSV67446816; called by muse, mutect2, varscan2
- MUC16 | c.2078G>A p.G693E | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.151); catalogued as COSV67446876; called by muse, mutect2, varscan2
- MUC17 | c.4600C>T p.L1534F | Missense Mutation (SNP) | VAF 180/388 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100074017; called by muse, mutect2, varscan2
- MUC5AC | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT deleterious (0); catalogued as COSV100650641; called by muse, mutect2, varscan2
- MXRA5 | c.6955G>A p.E2319K | Missense Mutation (SNP) | VAF 79/83 reads (95%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99477783; called by muse, mutect2, varscan2
- MYCBP2 | c.11296G>A p.D3766N (on ENST00000357337; = p.D3804N on NM_015057.5) | Missense Mutation (SNP) | VAF 77/193 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100630822; called by muse, mutect2, varscan2
- MYCBP2 | c.2404C>T p.L802F (on ENST00000357337; = p.L840F on NM_015057.5) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as COSV100630823; called by muse, mutect2, varscan2
- MYH1 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 105/135 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99875431, COSV99876302; called by muse, mutect2, varscan2
- MYH15 | c.94T>C p.F32L | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV99843679; called by muse, mutect2, varscan2
- MYH8 | c.1937C>T p.S646F | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs535957016, COSV101238482, COSV101238710; called by muse, mutect2, varscan2
- MYO18B | c.1888G>A p.D630N | Missense Mutation (SNP) | VAF 54/58 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1316516299, COSV100124205; called by muse, mutect2, varscan2
- MYO18B | c.5038G>A p.E1680K | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs749666378, COSV59130355, COSV59131815; called by muse, mutect2, varscan2
- MYO1F | c.1078C>G p.R360G | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV100596824; called by muse, mutect2, varscan2
- MYO3A | c.355G>A p.G119S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs928785273, COSV56320307; called by muse, mutect2, varscan2
- MYO9B | c.5288C>T p.P1763L | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV101261676; called by muse, mutect2
- MYOZ1 | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as COSV100831889; called by muse, mutect2, varscan2
- NASP | c.1854G>A p.M618I | Missense Mutation (SNP) | VAF 74/92 reads (80%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as COSV100601875; called by muse, mutect2, varscan2
- NASP | c.1855G>A p.A619T | Missense Mutation (SNP) | VAF 74/90 reads (82%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as COSV100601876; called by muse, mutect2, varscan2
- NCF4 | c.824+1G>A p.X275_splice | Splice Site (SNP) | VAF 27/29 reads (93%) | catalogued as COSV99957445; called by muse, mutect2, varscan2
- NCOA3 | c.4016G>A p.R1339K (on ENST00000371998 / NM_181659.3; = p.R1335K on NM_006534.4) | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1402011307, COSV100507763, COSV59070959; called by muse, mutect2, varscan2
- NDNF | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV65632535; called by muse, mutect2, varscan2
- NDST3 | c.679C>T p.H227Y | Missense Mutation (SNP) | VAF 65/85 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV56632147, COSV99631255; called by muse, mutect2, varscan2
- NDST4 | c.1840C>T p.L614F | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs761463844, COSV52109912; called by muse, mutect2, varscan2
- NEK11 | c.359T>A p.I120N | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs749410135, COSV100797769; called by muse, mutect2, varscan2
- NEXMIF | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV99281150; called by muse, mutect2, varscan2
- NEXMIF | c.105G>A p.M35I | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); catalogued as COSV99281151; called by muse, mutect2, varscan2
- NFKB2 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV99192929; called by muse, mutect2, varscan2
- NLRC3 | c.359G>A p.R120K | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as rs1157591250, COSV57086758; called by muse, mutect2, varscan2
- NLRC5 | c.2299C>T p.P767S | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV99347667; called by muse, mutect2, varscan2
- NLRP1 | c.1763C>A p.P588Q | Missense Mutation (SNP) | VAF 35/44 reads (80%) | SIFT tolerated (0.57); PolyPhen benign (0.051); catalogued as COSV99334605; called by muse, mutect2, varscan2
- NLRP10 | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs1380941090, COSV60780668; called by muse, mutect2, varscan2
- NLRP10 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 32/40 reads (80%) | SIFT tolerated (0.49); PolyPhen benign (0.031); catalogued as rs200564965, COSV100149778; called by muse, mutect2, varscan2
- NLRP12 | c.2848T>C p.F950L | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.814); catalogued as COSV100145457; called by muse, mutect2, varscan2
- NLRP3 | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV100276285; called by muse, mutect2, varscan2
- NMD3 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs769698988, COSV63618203; called by muse, mutect2, varscan2
- NME5 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.923); catalogued as COSV99496871; called by muse, mutect2, varscan2
- NOS1 | c.1484G>A p.G495D | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.404); catalogued as COSV100500860; called by muse, mutect2, varscan2
- NOSTRIN | c.910C>T p.P304S (on ENST00000317647 / NM_001039724.4; = p.P226S on NM_052946.3) | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs752294445, COSV100473778; called by muse, mutect2, varscan2
- NPVF | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 105/223 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs765775709, COSV99760271; called by muse, mutect2, varscan2
- NPY1R | c.707T>C p.I236T | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV99648909, COSV99648921; called by muse, mutect2, varscan2
- NPY2R | c.1093G>A p.V365I | Missense Mutation (SNP) | VAF 38/47 reads (81%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs773627985, COSV100279783; called by muse, mutect2, varscan2
- NRG3 | c.940C>T p.H314Y | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100932049; called by muse, mutect2, varscan2
- NRXN1 | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1439195215, COSV101277763; called by muse, mutect2, varscan2
- NSD1 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 51/79 reads (65%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.878); catalogued as COSV100729513; called by muse, mutect2, varscan2
- NTRK3 | c.2377C>T p.R793* (on ENST00000360948 / NM_001012338.2; = p.R779* on NM_002530.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 19/31 reads (61%) | catalogued as rs878997142, COSV100713118, COSV62297025, COSV62298410; called by muse, mutect2, varscan2
- NUAK1 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99777116; called by muse, mutect2, varscan2
- NUP107 | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 41/48 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99971863; called by muse, mutect2, varscan2
- NUP210 | c.4110G>A p.K1370= | Splice Region (SNP) | VAF 102/231 reads (44%) | catalogued as COSV99596465; called by muse, mutect2, varscan2
- NUP214 | c.3260C>T p.S1087L | Missense Mutation (SNP) | VAF 38/47 reads (81%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as rs567437017, COSV100845328; called by muse, mutect2, varscan2
- NXT2 | c.397T>A p.C133S (on ENST00000372106 / NM_001242617.2; = p.C188S on NM_018698.5) | Missense Mutation (SNP) | VAF 113/126 reads (90%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.894); catalogued as COSV99484162; called by muse, mutect2, varscan2
- NYAP2 | c.1814G>A p.G605E | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as rs1201117985, COSV99797322; called by muse, mutect2, varscan2
- NYNRIN | c.3139C>T p.P1047S | Missense Mutation (SNP) | VAF 30/40 reads (75%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.629); catalogued as rs757937013, COSV101230633; called by muse, mutect2, varscan2
- NYX | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100699437; called by muse, mutect2, varscan2
- OCLN | c.1073C>T p.S358L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs1280315953, COSV100783838; called by mutect2, varscan2
- OGFRL1 | c.826A>G p.K276E | Missense Mutation (SNP) | VAF 94/104 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV100965782; called by muse, mutect2, varscan2
- OIT3 | c.991G>A p.G331S | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.32); PolyPhen probably damaging (1); catalogued as COSV100468126; called by muse, mutect2, varscan2
- OLFM4 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 74/145 reads (51%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV54577477; called by muse, mutect2, varscan2
- OR1Q1 | c.906G>A p.M302I | Missense Mutation (SNP) | VAF 46/55 reads (84%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1227490619, COSV52917669; called by muse, mutect2, varscan2
- OR2A42 | c.291G>A p.M97I | Missense Mutation (SNP) | VAF 65/129 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101195834; called by muse, mutect2, varscan2
- OR2F1 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV67331300; called by muse, mutect2, varscan2
- OR2M3 | c.862C>T p.L288F | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV101513460; called by muse, mutect2, varscan2
- OR2T3 | c.691C>T p.H231Y | Missense Mutation (SNP) | VAF 67/108 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as COSV100613286; called by muse, mutect2, varscan2
- OR2T33 | c.207G>A p.M69I | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV58814130; called by muse, varscan2
- OR4A15 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 59/75 reads (79%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.059); catalogued as COSV100124204; called by muse, mutect2, varscan2
- OR4C12 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 35/42 reads (83%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.248); catalogued as COSV100078581; called by muse, mutect2, varscan2
- OR5H15 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs767529513, COSV100736696; called by muse, mutect2, varscan2
- OR6K3 | c.856G>A p.D286N (on ENST00000368146; = p.D270N on NM_001005327.2) | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.654); catalogued as COSV100933866; called by muse, mutect2, varscan2
- PADI1 | c.473A>G p.N158S | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100969160; called by muse, mutect2, varscan2
- PAK5 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 58/123 reads (47%) | catalogued as COSV100781458; called by muse, mutect2, varscan2
- PAPPA2 | c.970G>A p.G324R | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100866859; called by muse, mutect2, varscan2
- PAX2 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100695053; called by muse, mutect2, varscan2
- PCARE | c.1910G>A p.S637N | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV100527673; called by muse, mutect2, varscan2
- PCDH12 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.192); catalogued as COSV99190814; called by muse, mutect2, varscan2
- PCDHA11 | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100251747; called by muse, mutect2, varscan2
- PCDHA2 | c.1549G>A p.V517M | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100973477, COSV100973987; called by muse, mutect2, varscan2
- PCDHA2 | c.1927C>T p.P643S | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.057); catalogued as COSV65367244; called by muse, mutect2, varscan2
- PCDHAC2 | c.1334G>A p.G445E | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868960183, COSV53868735; called by muse, mutect2, varscan2
- PCDHB14 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.477); catalogued as rs1261708843, COSV99506067, COSV99506370; called by muse, mutect2, varscan2
- PCDHGA12 | c.2005C>T p.P669S | Missense Mutation (SNP) | VAF 63/172 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV99340906; called by muse, mutect2, varscan2
- PCDHGA5 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs375711929; called by muse, mutect2, varscan2
- PCDHGB6 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV53943510, COSV99541400; called by muse, mutect2, varscan2
- PCLO | c.14432C>T p.S4811F | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759723422, COSV100434154; called by muse, mutect2, varscan2
- PCLO | c.1945G>A p.D649N | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV61620983; called by muse, mutect2, varscan2
- PCLO | c.1466C>T p.P489L | Missense Mutation (SNP) | VAF 80/211 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1277859054, COSV100434157; called by muse, mutect2, varscan2
- PCNT | c.5577C>A p.F1859L | Missense Mutation (SNP) | VAF 42/51 reads (82%) | SIFT tolerated (0.17); PolyPhen benign (0.091); catalogued as COSV100855677, COSV64025360; called by muse, mutect2, varscan2
- PCTP | c.292G>T p.V98L | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.171); catalogued as COSV99273828; called by muse, mutect2, varscan2
- PDCD11 | c.1759T>G p.Y587D | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100874376; called by muse, mutect2, varscan2
- PDYN | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV54100904; called by muse, mutect2, varscan2
- PDZD2 | c.2419C>T p.R807C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs752110304, COSV99225611; called by mutect2, varscan2
- PGAP4 | c.739C>T p.H247Y | Missense Mutation (SNP) | VAF 54/63 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66387982; called by muse, mutect2, varscan2
- PGLYRP4 | c.212A>C p.Q71P | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT tolerated (0.67); PolyPhen benign (0.01); catalogued as COSV100668458; called by muse, mutect2, varscan2
- PGS1 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778707693, COSV53145009; called by muse, mutect2, varscan2
- PHGDH | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 83/220 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV65571787; called by muse, mutect2, varscan2
- PHGDH | c.824A>T p.H275L | Missense Mutation (SNP) | VAF 38/41 reads (93%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.886); catalogued as COSV101025145; called by muse, mutect2, varscan2
- PHIP | c.4141T>A p.L1381I | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV99244423; called by muse, mutect2, varscan2
- PKD1L1 | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.017); catalogued as COSV99220417; called by muse, mutect2, varscan2
- PKHD1L1 | c.5510C>T p.S1837L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as rs753240178, COSV101006460; called by muse, mutect2, varscan2
- PKP2 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 43/86 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV50740851; called by muse, mutect2, varscan2
- PLA2G4D | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 29/35 reads (83%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.949); catalogued as rs1175362455, COSV99299838; called by muse, mutect2, varscan2
- PLCB1 | c.1990C>T p.P664S | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as rs771607069, COSV62055161; called by muse, mutect2, varscan2
- PLCB4 | c.92T>C p.F31S | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1281633866, COSV99595986; called by muse, mutect2, varscan2
- PLCE1 | c.3472C>T p.P1158S | Missense Mutation (SNP) | VAF 92/147 reads (63%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as rs1234627666, COSV99595639; called by muse, mutect2, varscan2
- PLEKHA6 | c.425G>A p.S142N | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.06); catalogued as COSV99692315; called by muse, mutect2, varscan2
- PLS1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 55/139 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as rs778735363, COSV100538181; called by muse, mutect2, varscan2
- PNLIPRP2 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as COSV100077836; called by muse, mutect2, varscan2
- PNMA5 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 35/40 reads (88%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as rs1179775851, COSV100721663; called by muse, mutect2, varscan2
- POTEF | c.1750C>T p.P584S | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.015); catalogued as COSV100665053; called by mutect2, varscan2
- POTEF | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 116/418 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV100665054, COSV62541286; called by muse, mutect2, varscan2
- PPP1R32 | c.1208G>A p.R403K | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100087884; called by muse, mutect2, varscan2
- PPP1R3A | c.1984C>T p.Q662* | Nonsense Mutation (SNP) | VAF 94/201 reads (47%) | catalogued as rs1360103552, COSV99493331; called by muse, mutect2, varscan2
- PRB2 | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 214/518 reads (41%) | SIFT tolerated, low confidence (0.34); PolyPhen possibly damaging (0.489); catalogued as rs770261707, COSV101231445, COSV66984400; called by muse, varscan2
- PRB4 | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 166/383 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.688); catalogued as COSV54395134; called by muse, mutect2, varscan2
- PREPL | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV99576273; called by muse, mutect2, varscan2
- PRR16 | c.625G>A p.E209K (on ENST00000407149 / NM_001300783.2; = p.E186K on NM_016644.2) | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV65395945; called by muse, mutect2, varscan2
- PRR35 | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1260640591, COSV99552159; called by muse, mutect2
- PRRX1 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV99509514; called by muse, mutect2, varscan2
- PTPN22 | c.2078C>T p.P693L (on ENST00000359785 / NM_001193431.2; = p.P638L on NM_012411.5) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.238); catalogued as rs763836317, COSV63086358; called by muse, mutect2, varscan2
- PTPN22 | c.2077C>T p.P693S (on ENST00000359785 / NM_001193431.2; = p.P638S on NM_012411.5) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.117); catalogued as rs751324264, COSV63086042; called by muse, mutect2, varscan2
- PTPRE | c.1551G>A p.W517* | Nonsense Mutation (SNP) | VAF 22/27 reads (81%) | catalogued as COSV54549280; called by muse, mutect2, varscan2
- PTPRU | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 42/52 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV100113138; called by muse, mutect2
- PUS1 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745689913, COSV100435125, COSV59035032; called by muse, mutect2, varscan2
- PWWP3B | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.12); PolyPhen benign (0.117); catalogued as rs1336211694, COSV61801031; called by muse, mutect2, varscan2
- PXK | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs751265673, COSV100244198; called by muse, mutect2, varscan2
- RALYL | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV72819029, COSV72826110; called by muse, mutect2, varscan2
- RANBP2 | c.2584C>T p.H862Y | Missense Mutation (SNP) | VAF 188/459 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV51696094; called by muse, mutect2, varscan2
- RAPGEF2 | c.4010C>A p.S1337* | Nonsense Mutation (SNP) | VAF 17/31 reads (55%) | catalogued as COSV100031365; called by muse, mutect2, varscan2
- RAPGEF6 | c.1897C>T p.P633S | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.878); catalogued as COSV57256142; called by muse, mutect2, varscan2
- RBBP6 | c.4067C>T p.P1356L | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV100154700; called by muse, mutect2, varscan2
- RBM12 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58293187; called by muse, mutect2, varscan2
- RBP3 | c.2507C>T p.S836L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.174); catalogued as rs1432808139; called by muse, mutect2, varscan2
- RELN | c.7696G>A p.D2566N | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as COSV100634105; called by muse, mutect2, varscan2
- RESF1 | c.2303T>C p.L768P | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1256519619, COSV100440425; called by muse, mutect2, varscan2
- REV3L | c.2884C>T p.R962* | Nonsense Mutation (SNP) | VAF 38/44 reads (86%) | catalogued as COSV100725347; called by muse, mutect2, varscan2
- RFX2 | c.1514G>A p.S505N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as COSV100353880; called by mutect2, varscan2
- RFX3 | c.816G>A p.M272I | Missense Mutation (SNP) | VAF 56/63 reads (89%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as COSV100175396; called by muse, mutect2, varscan2
- RIMS4 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.277); catalogued as COSV100865155; called by muse, mutect2, varscan2
- RIPPLY3 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 47/55 reads (85%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.013); catalogued as COSV100289346; called by muse, mutect2, varscan2
- RNF17 | c.1850G>A p.G617D | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV55055621; called by muse, mutect2, varscan2
- RP1 | c.479G>A p.R160K | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV99607985; called by muse, mutect2, varscan2
- RPE65 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 96/104 reads (92%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.862); catalogued as rs577193739, COSV52016613; called by muse, mutect2, varscan2
- RPRD2 | c.881C>T p.T294I | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV100955167; called by muse, mutect2, varscan2
- RPS6KA1 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 120/291 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1273807884, COSV100837954; called by mutect2, varscan2
- RTP5 | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100574762; called by muse, mutect2, varscan2
- RYR1 | c.3581G>A p.G1194E | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1262460201, COSV100616185; called by muse, mutect2, varscan2
- RYR1 | c.11260G>A p.E3754K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV62090455; called by muse, mutect2, varscan2
- RYR2 | c.12932G>A p.S4311N | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV100771477; called by muse, mutect2, varscan2
- SBSPON | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); catalogued as rs202151174; called by muse, mutect2, varscan2
- SCAPER | c.2117G>A p.R706K | Missense Mutation (SNP) | VAF 54/66 reads (82%) | SIFT tolerated (0.33); PolyPhen benign (0.316); catalogued as COSV57758318; called by muse, mutect2, varscan2
- SCLY | c.1109C>T p.S370F (on ENST00000651534; = p.S362F on NM_016510.7) | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54541122; called by muse, mutect2, varscan2
- SCN1A | c.4837A>G p.I1613V (on ENST00000303395 / NM_001202435.3; = p.I1602V on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.456); catalogued as rs768031961, COSV100321012; called by muse, mutect2, varscan2
- SCN2A | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 74/170 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV51836073, COSV51840235; called by muse, mutect2, varscan2
- SCN5A | c.1157G>A p.G386E | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199473567, CM100651, COSV61130476; ClinVar: not provided; called by muse, mutect2, varscan2
- SCN5A | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs1404917416, COSV100349231; called by muse, mutect2, varscan2
- SCNN1A | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs200557019; called by muse, mutect2, varscan2
- SDK2 | c.1504C>T p.P502S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1324632270, COSV101167892; called by muse, mutect2, varscan2
- SDR16C5 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.052); catalogued as COSV100374051; called by muse, mutect2, varscan2
- SEC16A | c.6523C>T p.P2175S | Missense Mutation (SNP) | VAF 42/49 reads (86%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV99259078; called by muse, mutect2, varscan2
- SEMG1 | c.1021C>T p.Q341* | Nonsense Mutation (SNP) | VAF 23/60 reads (38%) | catalogued as COSV99725345; called by muse, mutect2, varscan2
- SERPINB3 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 33/40 reads (83%) | SIFT tolerated (0.09); PolyPhen benign (0.394); catalogued as rs143123968, COSV52190153; called by muse, mutect2, varscan2
- SERPINB5 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 43/50 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV101237672; called by muse, mutect2, varscan2
- SERPINB7 | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 55/69 reads (80%) | SIFT tolerated (0.68); PolyPhen benign (0.012); catalogued as rs1341450625, COSV100320902; called by muse, mutect2, varscan2
- SH2D5 | c.707G>T p.R236L (on ENST00000444387 / NM_001103161.2; = p.R152L on NM_001103160.2) | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV100903869, COSV66707297; called by muse, mutect2, varscan2
- SH3TC1 | c.2237G>A p.R746K | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT tolerated (0.39); PolyPhen benign (0.061); catalogued as rs774676331, COSV99795047; called by muse, mutect2, varscan2
- SH3TC2 | c.3607C>T p.P1203S | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.66); PolyPhen benign (0.021); catalogued as rs764665807, COSV100101981; called by muse, mutect2, varscan2
- SHISA2 | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 34/65 reads (52%) | catalogued as COSV100096495; called by muse, mutect2, varscan2
- SHROOM2 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148416024, COSV101098838; called by muse, varscan2
- SHROOM4 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99173795; called by muse, mutect2
- SIGLEC11 | c.2089C>T p.P697S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); catalogued as rs1258425203, COSV101357069; called by muse, mutect2, varscan2
- SIPA1L2 | c.4415C>T p.S1472L | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.842); catalogued as rs150962063, COSV53384982; called by muse, mutect2, varscan2
- SIRPB1 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs748979806, COSV99498471; called by muse, mutect2, varscan2
- SIX4 | c.2134C>T p.R712C | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.249); catalogued as rs756235258, COSV53671234; called by muse, mutect2, varscan2
- SLAMF1 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs760706977, COSV52500533; called by muse, mutect2, varscan2
- SLAMF9 | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as COSV100928159; called by muse, mutect2, varscan2
- SLC12A8 | c.1169A>G p.N390S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.312); catalogued as COSV100102677; called by muse, varscan2
- SLC22A1 | c.1531C>G p.L511V | Missense Mutation (SNP) | VAF 115/136 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV100266855; called by muse, mutect2, varscan2
- SLC22A1 | c.1532T>C p.L511P | Missense Mutation (SNP) | VAF 115/136 reads (85%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100266857; called by muse, mutect2, varscan2
- SLC27A6 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as rs976216647, COSV99323063; called by muse, mutect2, varscan2
- SLC35F4 | c.1466A>T p.E489V (on ENST00000339762 / NM_001352015.2; = p.E453V on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as COSV100333999; called by muse, mutect2, varscan2
- SLC35G2 | c.1001G>A p.G334E | Missense Mutation (SNP) | VAF 117/280 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV101262052; called by muse, mutect2, varscan2
- SLC66A3 | c.359T>G p.L120R | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1277867952, COSV99706297; called by muse, mutect2, varscan2
- SLC7A6 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as rs1243169509, COSV99546673; called by muse, mutect2, varscan2
- SLC7A9 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as rs201766636, COSV99195359; called by muse, mutect2, varscan2
- SLC9A4 | c.1403G>A p.G468E | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1400709902, COSV54829060; called by muse, mutect2, varscan2
- SLC9C2 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs528983665, COSV62943283; called by muse, mutect2, varscan2
- SLCO1B1 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as rs1378329082, COSV57015757; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2135C>T p.S712F (on ENST00000540229 / NM_001371097.1; = p.S651F on NM_001009562.4) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1018805704, COSV67447614; called by muse, mutect2, varscan2
- SLFN12 | c.1489A>G p.I497V | Missense Mutation (SNP) | VAF 67/164 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV59226511; called by muse, mutect2, varscan2
- SLIT1 | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 51/82 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs750943079, COSV56595388; called by muse, mutect2, varscan2
- SLIT2 | c.2926G>A p.E976K | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV56569359; called by muse, mutect2
- SLMAP | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV99908804; called by muse, mutect2, varscan2
- SORL1 | c.5548G>A p.A1850T | Missense Mutation (SNP) | VAF 44/62 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV99493549, COSV99494388; called by muse, mutect2, varscan2
- SOSTDC1 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.133); catalogued as COSV100194308; called by muse, varscan2
- SOX13 | c.1128C>A p.F376L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.084); catalogued as rs1293743244, COSV65826608, COSV99689988; called by muse, mutect2, varscan2
- SOX13 | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756759597, COSV99689989; called by muse, varscan2
- SOX8 | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV99559307; called by muse, mutect2
- SPACA4 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV99614148; called by muse, mutect2, varscan2
- SPHKAP | c.4942G>A p.E1648K (on ENST00000392056 / NM_001142644.2; = p.E1619K on NM_030623.3) | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1168622403, COSV60892198; called by muse, mutect2, varscan2
- SPOCK1 | c.565C>T p.P189S | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.68); PolyPhen benign (0.04); catalogued as COSV99969918; called by muse, mutect2, varscan2
- SPOP | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 71/165 reads (43%) | SIFT tolerated (1); PolyPhen possibly damaging (0.524); catalogued as COSV100753451; called by muse, mutect2, varscan2
- SPTA1 | c.6987G>A p.G2329= | Splice Region (SNP) | VAF 20/44 reads (45%) | catalogued as rs1486529922, COSV63756285; called by muse, mutect2, varscan2
- SSTR2 | c.874G>A p.G292S | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.305); catalogued as rs562871663, COSV100192116; called by muse, mutect2, varscan2
- SSX1 | c.279G>A p.Q93= | Splice Region (SNP) | VAF 67/77 reads (87%) | catalogued as COSV100976399, COSV65355199; called by muse, mutect2, varscan2
- STAB2 | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 64/77 reads (83%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66344027; called by muse, mutect2, varscan2
- STARD13 | c.285T>G p.H95Q | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55234609, COSV99716097; called by muse, mutect2, varscan2
- STARD6 | c.535T>A p.L179M | Missense Mutation (SNP) | VAF 29/33 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100323488; called by muse, mutect2, varscan2
- STK11IP | c.3085C>T p.P1029S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.935); catalogued as rs1275428515, COSV99823064; called by muse, mutect2, varscan2
- STK19 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 96/111 reads (86%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.166); catalogued as COSV100514749, COSV61713357; called by muse, mutect2, varscan2
- STXBP5L | c.1727C>T p.P576L | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as rs747217368, COSV56501092; called by muse, mutect2, varscan2
- SUN1 | c.1676C>T p.S559F (on ENST00000405266 / NM_001367651.1; = p.S439F on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.959); catalogued as COSV101273051; called by muse, mutect2, varscan2
- SUPV3L1 | c.613C>T p.H205Y | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100669745; called by muse, mutect2, varscan2
- SURF2 | c.652A>C p.T218P | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as COSV100914356; called by muse, mutect2
- SYNE1 | c.5783G>A p.G1928D (on ENST00000367255 / NM_182961.4; = p.G1935D on NM_033071.3) | Missense Mutation (SNP) | VAF 69/78 reads (88%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as rs1241708653, COSV99569895; called by muse, mutect2, varscan2
- SYT1 | c.643G>A p.V215I | Missense Mutation (SNP) | VAF 50/69 reads (72%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV99696128; called by muse, mutect2, varscan2
- SZT2 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 61/68 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368761999, COSV60290526; called by muse, mutect2, varscan2
- TAF4 | c.2480C>T p.S827L | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as rs755551996, COSV53343162; called by muse, mutect2, varscan2
- TAS1R1 | c.1373G>A p.G458E | Missense Mutation (SNP) | VAF 121/135 reads (90%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV59840630; called by muse, mutect2, varscan2
- TAS2R7 | c.873A>C p.K291N | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99553858; called by muse, mutect2, varscan2
- TBC1D1 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 32/40 reads (80%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs1182970964, COSV99791569; called by muse, mutect2, varscan2
- TBC1D31 | c.1088C>T p.S363F | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99782916; called by muse, mutect2, varscan2
- TCHH | c.4169G>A p.R1390K | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV100915224; called by muse, mutect2, varscan2
- TCTN1 | c.1553C>T p.S518F (on ENST00000551590 / NM_001173975.3; = p.S504F on NM_024549.6) | Missense Mutation (SNP) | VAF 47/57 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1175762545, COSV99657275; called by muse, mutect2, varscan2
- TDRD5 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99676554; called by muse, mutect2, varscan2
- TENM2 | c.2042G>A p.G681E (on ENST00000518659 / NM_001122679.2; = p.G449E on NM_001080428.3) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV101319017; called by muse, mutect2, varscan2
- TEP1 | c.1766C>T p.S589L | Missense Mutation (SNP) | VAF 35/41 reads (85%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as rs143898219; called by muse, mutect2, varscan2
- TEX11 | c.1390G>A p.A464T (on ENST00000344304; = p.A449T on NM_031276.3) | Missense Mutation (SNP) | VAF 33/36 reads (92%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.852); catalogued as COSV100721935; called by muse, mutect2, varscan2
- TGM2 | c.1823C>T p.S608F | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1302893115, COSV100821597, COSV100821683; called by muse, mutect2, varscan2
- THBS4 | c.651G>A p.G217= | Splice Region (SNP) | VAF 37/75 reads (49%) | catalogued as rs1235355136, COSV100644344; called by muse, mutect2, varscan2
- THEM5 | c.659C>G p.A220G | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV100917258, COSV64312717; called by muse, mutect2, varscan2
- THNSL1 | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.111); catalogued as COSV100896239; called by muse, mutect2, varscan2
- TMC5 | c.1149G>A p.R383= (on ENST00000396229 / NM_001105248.1; = p.R137= on NM_024780.5) | Splice Region (SNP) | VAF 31/65 reads (48%) | catalogued as COSV54901278; called by muse, mutect2, varscan2
- TMEM131 | c.4697C>T p.S1566F | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.305); catalogued as COSV99488383; called by muse, mutect2, varscan2
- TMEM145 | c.778C>T p.L260F | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs995924004, COSV100003965; called by muse, mutect2, varscan2
- TMEM200A | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 75/85 reads (88%) | SIFT deleterious (0.04); PolyPhen benign (0.351); catalogued as COSV99759535; called by muse, mutect2, varscan2
- TMEM59L | c.619G>A p.V207M | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); catalogued as rs762607917, COSV99450347; called by muse, mutect2, varscan2
- TMEM60 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV99301960; called by muse, mutect2, varscan2
- TMPRSS11A | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT tolerated (1); PolyPhen benign (0.238); catalogued as COSV100602747; called by muse, mutect2, varscan2
- TMPRSS9 | c.1342G>A p.E448K (on ENST00000648592; = p.E414K on NM_182973.2) | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1466001057, COSV60226791; called by muse, mutect2, varscan2
- TNFRSF10B | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV99375477; called by muse, mutect2, varscan2
- TNR | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs750811658, COSV54921548; called by muse, mutect2, varscan2
- TNRC6C | c.4225G>A p.V1409I | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as rs749492805, COSV100050197; called by muse, mutect2, varscan2
- TNXB | c.8086G>A p.D2696N (on ENST00000647633; = p.D2449N on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/82 reads (77%) | SIFT tolerated (0.06); PolyPhen benign (0.358); catalogued as COSV64485876; called by muse, mutect2, varscan2
- TOGARAM2 | c.2047G>A p.A683T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as COSV65424153; called by muse, mutect2, varscan2
- TOMM7 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV100626941; called by muse, varscan2
- TPO | c.2356G>A p.G786R | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.092); catalogued as COSV61098978, COSV61106892; called by muse, mutect2, varscan2
- TPO | c.2357G>A p.G786E | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.346); catalogued as rs1194329219, COSV61103522; called by muse, mutect2, varscan2
- TRAV24 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as rs867921817; called by muse, mutect2, varscan2
- TRHDE | c.2622G>A p.M874I | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.756); catalogued as COSV53844913; called by muse, mutect2, varscan2
- TRIM58 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV100825175; called by muse, mutect2, varscan2
- TRPM2 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 59/71 reads (83%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs200293453, COSV55968116; called by muse, mutect2, varscan2
- TRPM2 | c.1853C>T p.T618I | Missense Mutation (SNP) | VAF 148/168 reads (88%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.578); catalogued as rs1162085077, COSV100309033; called by muse, mutect2, varscan2
- TRPM6 | c.2314C>T p.P772S | Missense Mutation (SNP) | VAF 73/75 reads (97%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100666604; called by muse, mutect2, varscan2
- TTC13 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.361); catalogued as rs775455371, COSV64168757; called by muse, mutect2, varscan2
- TTC25 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs782333806, COSV101102925; called by muse, mutect2, varscan2
- TTN | c.77575G>A p.E25859K (on ENST00000591111; = p.E18435K on NM_003319.4) | Missense Mutation (SNP) | VAF 65/164 reads (40%) | PolyPhen benign (0.123); catalogued as rs375422359, COSV60212479; called by muse, mutect2, varscan2
- TTN | c.43436T>C p.V14479A (on ENST00000591111; = p.V7055A on NM_003319.4) | Missense Mutation (SNP) | VAF 37/74 reads (50%) | PolyPhen benign (0.001); catalogued as rs745999025, COSV100619210; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBA3E | c.647A>G p.N216S | Missense Mutation (SNP) | VAF 77/154 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.266); catalogued as rs552150302, COSV99919865; called by muse, mutect2, varscan2
- U2AF2 | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.85); PolyPhen benign (0.014); catalogued as COSV100454332; called by muse, mutect2, varscan2
- UBE2E3 | c.602G>A p.W201* | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as rs1377747244, COSV101150473; called by muse, mutect2, varscan2
- UNC5A | c.2414A>C p.N805T | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.088); catalogued as COSV99458808; called by muse, mutect2, varscan2
- UROC1 | c.1694C>T p.S565F | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52031265, COSV99331741; called by muse, mutect2, varscan2
- USHBP1 | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV53102526, COSV53104723; called by muse, mutect2, varscan2
- USP13 | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99831366; called by muse, mutect2, varscan2
- USP5 | c.1286C>T p.S429F | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99978799; called by muse, mutect2, varscan2
- VPS8 | c.2971G>A p.V991I (on ENST00000625842 / NM_001349294.1; = p.V989I on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1450781017, COSV99802747; called by muse, mutect2, varscan2
- VSTM2L | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as COSV65096270; called by muse, mutect2, varscan2
- VWA3A | c.2483G>A p.G828E | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs770346742, COSV100241052, COSV99076819; called by muse, varscan2
- WARS1 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 34/42 reads (81%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as COSV100690221; called by muse, mutect2, varscan2
- WASF2 | c.1165G>A p.G389R | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV101420798; called by muse, mutect2, varscan2
- WDR49 | c.1252C>T p.H418Y (on ENST00000308378 / NM_001366158.1; = p.H759Y on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as rs774719164, COSV100392897, COSV57701268; called by muse, mutect2, varscan2
- WNK2 | c.6752G>A p.G2251E | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs1305279901, COSV99943302; called by muse, mutect2, varscan2
- XKR8 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs187574926, COSV100874586; called by muse, mutect2, varscan2
- YEATS2 | c.657A>G p.I219M | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100527961; called by muse, varscan2
- ZBED2 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as COSV99343107; called by muse, mutect2, varscan2
- ZCCHC4 | c.1472C>T p.S491F | Missense Mutation (SNP) | VAF 34/38 reads (89%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.459); catalogued as COSV100255358; called by muse, mutect2, varscan2
- ZDBF2 | c.3955G>A p.D1319N | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV100985089; called by muse, mutect2, varscan2
- ZFHX4 | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as rs267601996, COSV50578199; called by muse, mutect2, varscan2
- ZFHX4 | c.7612A>T p.M2538L | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.618); catalogued as COSV99264531; called by muse, mutect2, varscan2
- ZFHX4 | c.8741G>A p.G2914E | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99264533; called by muse, varscan2
- ZFHX4 | c.8752C>T p.P2918S | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.835); catalogued as rs1404887872, COSV50525534; called by muse, varscan2
- ZIC5 | c.1543C>T p.H515Y | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99940650; called by muse, mutect2, varscan2
- ZMIZ2 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.146); catalogued as rs760181629, COSV54806963; called by muse, mutect2, varscan2
- ZNF160 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV100762381; called by muse, mutect2, varscan2
- ZNF20 | c.115A>G p.T39A | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs1232876465, COSV100503085; called by muse, mutect2, varscan2
- ZNF300 | c.1090C>T p.Q364* | Nonsense Mutation (SNP) | VAF 26/80 reads (33%) | catalogued as rs1483004989, COSV99199909; called by muse, mutect2, varscan2
- ZNF429 | c.1478C>T p.S493F | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT tolerated (0.28); PolyPhen benign (0.103); catalogued as COSV100641964; called by muse, mutect2, varscan2
- ZNF442 | c.1576A>T p.S526C | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.896); catalogued as COSV99664426; called by muse, mutect2, varscan2
- ZNF578 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs761763141, COSV69736524; called by muse, mutect2, varscan2
- ZNF592 | c.2828C>T p.P943L | Missense Mutation (SNP) | VAF 21/23 reads (91%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as rs1355219567, COSV55437340; called by muse, mutect2, varscan2
- ZNF607 | c.1327C>T p.H443Y | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1404520975, COSV100777924; called by muse, mutect2, varscan2
- ZNF609 | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 46/53 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100441327; called by muse, mutect2, varscan2
- ZNF816 | c.1354C>T p.P452S | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99554623; called by muse, mutect2, varscan2
- ZNF836 | c.1175del p.G392Efs*43 | Frame Shift Del (DEL) | VAF 7/69 reads (10%) | catalogued as COSV59085409; called by mutect2, pindel
- ZNF98 | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.404); catalogued as COSV63337207; called by mutect2, varscan2
- ZNF99 | c.1643A>G p.N548S | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.042); catalogued as rs764884829, COSV101233872; called by muse, mutect2, varscan2
- ZPLD1 | c.925C>T p.L309F (on ENST00000466937 / NM_001329788.1; = p.L325F on NM_175056.2) | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.851); catalogued as COSV60354270; called by muse, mutect2, varscan2
- ZRANB3 | c.1847C>T p.T616I | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs369012868, COSV99924024; called by muse, mutect2, varscan2
- ZSCAN10 | c.817G>A p.E273K (on ENST00000252463; = p.E328K on NM_032805.3) | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99374144; called by muse, mutect2, varscan2
- ZSCAN21 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV52849939; called by muse, mutect2, varscan2
- AQP12A | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.322); called by muse, mutect2
- ASPM | c.5544_5555dup p.Q1849_I1852dup | In Frame Ins (INS) | VAF 23/86 reads (27%) | called by mutect2, varscan2
- FAM111B | c.970_979del p.I324Lfs*4 | Frame Shift Del (DEL) | VAF 40/47 reads (85%) | called by mutect2, pindel, varscan2
- FRG2B | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by mutect2, varscan2
- GGNBP2 | c.1417G>T p.E473* | Nonsense Mutation (SNP) | VAF 59/132 reads (45%) | called by muse, mutect2, varscan2
- HNRNPK | c.1093-3dup | Splice Region (INS) | VAF 56/90 reads (62%) | called by mutect2, pindel, varscan2
- MAP1B | c.1234_1236del p.F412del | In Frame Del (DEL) | VAF 25/81 reads (31%) | called by mutect2, pindel, varscan2
- MUC2 | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 62/76 reads (82%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- NISCH | c.2017G>T p.E673* | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- PCDH15 | c.3089G>A p.G1030D | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.109); called by muse, mutect2
- PRAMEF18 | c.639G>A p.W213* | Nonsense Mutation (SNP) | VAF 221/914 reads (24%) | called by muse, mutect2, varscan2
- RPGRIP1L | c.3445del p.I1149Ffs*6 | Frame Shift Del (DEL) | VAF 61/101 reads (60%) | called by mutect2, pindel, varscan2
- SRSF7 | c.437_439delinsTA p.S146Lfs*39 | Frame Shift Del (DEL) | VAF 46/155 reads (30%) | called by pindel, varscan2*
- ZNF488 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABAT | c.744C>T p.F248= | Silent (SNP) | VAF 89/213 reads (42%) | catalogued as COSV99190983; called by muse, mutect2, varscan2
- ABCA13 | c.13602G>A p.K4534= | Silent (SNP) | VAF 47/88 reads (53%) | catalogued as rs202160840, COSV68949410; called by muse, mutect2, varscan2
- ABCA3 | c.3747C>T p.F1249= | Silent (SNP) | VAF 73/152 reads (48%) | catalogued as COSV100068070; called by muse, mutect2, varscan2
- ABLIM2 | c.1344G>A p.G448= (on ENST00000341937 / NM_001130084.2; = p.G396= on NM_032432.5) | Silent (SNP) | VAF 37/48 reads (77%) | catalogued as COSV99589910; called by muse, mutect2, varscan2
- ABR | c.165C>T p.T55= | Silent (SNP) | VAF 46/53 reads (87%) | catalogued as rs1225505791, COSV100215490; called by muse, mutect2, varscan2
- ACSM2B | c.300C>T p.A100= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as rs1405549755, COSV100312878; called by muse, mutect2, varscan2
- ADAMTS19 | c.1734T>A p.L578= | Silent (SNP) | VAF 31/63 reads (49%) | catalogued as COSV50744544, COSV99179350; called by muse, mutect2, varscan2
- ADGRB1 | c.2880C>T p.L960= | Silent (SNP) | VAF 46/79 reads (58%) | catalogued as COSV100029891; called by muse, mutect2, varscan2
- ADGRB3 | c.2796G>A p.Q932= | Silent (SNP) | VAF 80/95 reads (84%) | catalogued as COSV53256080, COSV99485845; called by muse, mutect2, varscan2
- ADGRV1 | c.1353G>A p.P451= | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as rs749412864, COSV67985622; called by muse, mutect2, varscan2
- ADGRV1 | c.17364G>A p.G5788= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV101316153; called by muse, mutect2, varscan2
- ADO | c.742C>T p.L248= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as COSV101060470; called by muse, mutect2, varscan2
- ADORA3 | c.561C>T p.F187= | Silent (SNP) | VAF 45/114 reads (39%) | catalogued as COSV53985112; called by muse, mutect2, varscan2
- AHDC1 | c.750C>T p.S250= | Silent (SNP) | VAF 42/52 reads (81%) | catalogued as rs746717563, COSV99899486; called by muse, mutect2, varscan2
- AHSG | c.738C>T p.T246= | Silent (SNP) | VAF 32/67 reads (48%) | catalogued as COSV99890129; called by muse, mutect2, varscan2
- AK5 | c.1305G>C p.V435= (on ENST00000354567 / NM_174858.3; = p.V409= on NM_012093.4) | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV100643073; called by muse, mutect2, varscan2
- AL121899.2 | c.156G>A p.R52= | Silent (SNP) | VAF 52/118 reads (44%) | catalogued as COSV101198532; called by muse, mutect2, varscan2
- AMER3 | c.516G>A p.E172= | Silent (SNP) | VAF 43/93 reads (46%) | catalogued as rs779212501, COSV100366609; called by muse, mutect2, varscan2
- ANK1 | c.2616C>T p.I872= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV99225785; called by muse, mutect2, varscan2
- ANO10 | c.435T>C p.G145= | Silent (SNP) | VAF 36/69 reads (52%) | catalogued as COSV99428688; called by muse, mutect2, varscan2
- AP2A1 | c.1215C>T p.I405= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as rs1344580727, COSV62820751; called by muse, mutect2, varscan2
- AP4M1 | c.1122C>T p.L374= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV100385016; called by muse, mutect2, varscan2
- APCDD1L | c.1032G>A p.R344= | Silent (SNP) | VAF 37/74 reads (50%) | catalogued as COSV100954031; called by muse, mutect2, varscan2
- APP | c.1905C>T p.N635= | Silent (SNP) | VAF 51/56 reads (91%) | catalogued as rs768007693, COSV100695967; called by muse, mutect2, varscan2
- ARHGEF1 | c.414C>T p.F138= | Silent (SNP) | VAF 34/71 reads (48%) | catalogued as rs782354288, COSV61528065; called by muse, mutect2, varscan2
- ARHGEF6 | c.906C>T p.A302= | Silent (SNP) | VAF 32/39 reads (82%) | catalogued as COSV99166538; called by muse, mutect2, varscan2
- ARIH1 | c.1542C>T p.S514= | Silent (SNP) | VAF 23/33 reads (70%) | catalogued as COSV65912649; called by muse, mutect2, varscan2
- ATF7IP | c.1482C>T p.V494= | Silent (SNP) | VAF 36/81 reads (44%) | catalogued as COSV99661849; called by muse, mutect2, varscan2
- ATRX | c.6669G>A p.K2223= | Silent (SNP) | VAF 101/122 reads (83%) | catalogued as COSV100971078; called by muse, mutect2, varscan2
- ATXN7 | c.1473C>T p.S491= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV99894699; called by muse, mutect2, varscan2
- BDKRB1 | c.438G>A p.R146= | Silent (SNP) | VAF 33/38 reads (87%) | catalogued as COSV99387926; called by muse, mutect2, varscan2
- BRD1 | c.2826C>T p.S942= (on ENST00000216267 / NM_001349940.1; = p.S1073= on NM_001304808.3) | Silent (SNP) | VAF 52/63 reads (83%) | catalogued as rs755696832, COSV99349970; called by muse, mutect2, varscan2
- C1orf94 | c.1743G>A p.G581= (on ENST00000488417 / NM_001134734.2; = p.G391= on NM_032884.5) | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as COSV100975043; called by muse, mutect2, varscan2
- C3 | c.2985C>T p.V995= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV99835974; called by muse, mutect2, varscan2
- C6 | c.957G>A p.V319= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs1410535491, COSV54708008; called by muse, mutect2, varscan2
- CALCRL | c.405G>A p.V135= | Silent (SNP) | VAF 53/130 reads (41%) | catalogued as rs1489149939, COSV101130999; called by muse, mutect2, varscan2
- CALML3 | c.285G>A p.K95= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as rs143468855; called by muse, mutect2, varscan2
- CAMKV | c.1185C>T p.T395= | Silent (SNP) | VAF 76/217 reads (35%) | catalogued as rs756724824, COSV99615696; called by muse, mutect2, varscan2
- CAPN13 | c.1761C>T p.L587= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV99700200, COSV99700436; called by muse, mutect2, varscan2
- CCDC191 | c.135G>T p.V45= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs763298465, COSV99878450; called by muse, mutect2, varscan2
- CCN4 | c.591C>T p.P197= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV99137200; called by muse, mutect2, varscan2
- CD1B | c.93C>T p.I31= | Silent (SNP) | VAF 75/203 reads (37%) | catalogued as rs1282790491, COSV100939164, COSV100939254; called by muse, mutect2, varscan2
- CD2 | c.567G>A p.G189= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs892662293, COSV101040442; called by muse, mutect2, varscan2
- CD22 | c.603G>A p.R201= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs778570157, COSV99323413; called by muse, mutect2, varscan2
- CDC23 | c.879C>T p.D293= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV101203129; called by muse, mutect2, varscan2
- CDCA5 | c.123C>T p.L41= | Silent (SNP) | VAF 15/17 reads (88%) | catalogued as COSV99297901; called by muse, mutect2, varscan2
- CDH6 | c.1761G>A p.R587= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV99419740; called by muse, mutect2, varscan2
- CDK3 | c.693C>T p.T231= | Silent (SNP) | VAF 76/173 reads (44%) | catalogued as COSV56912479; called by muse, mutect2, varscan2
- CFAP36 | c.750G>A p.E250= | Silent (SNP) | VAF 38/93 reads (41%) | catalogued as rs757368168, COSV99702230; called by muse, mutect2, varscan2
- CGB1 | c.303C>A p.A101= | Silent (SNP) | VAF 22/123 reads (18%) | catalogued as rs1262024856, COSV100031693; called by muse, varscan2
- CHCHD5 | c.12C>T p.A4= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as COSV100260869; called by muse, mutect2, varscan2
- CHD4 | c.390C>T p.S130= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs368112823; called by muse, mutect2, varscan2
- CHD5 | c.3396C>T p.S1132= | Silent (SNP) | VAF 26/30 reads (87%) | catalogued as rs1331252930, COSV99314133; called by muse, mutect2, varscan2
- CHRM3 | c.213C>T p.I71= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs199705116, COSV99698113; called by muse, mutect2, varscan2
- CHRNA2 | c.1026C>T p.S342= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as COSV99532348; called by muse, mutect2, varscan2
- CHRNB3 | c.132C>T p.V44= | Silent (SNP) | VAF 35/64 reads (55%) | catalogued as COSV51497320; called by muse, mutect2, varscan2
- CILP2 | c.1710C>T p.I570= | Silent (SNP) | VAF 42/162 reads (26%) | catalogued as rs150610610; called by muse, mutect2, varscan2
- CNGA3 | c.600G>A p.L200= | Silent (SNP) | VAF 41/94 reads (44%) | catalogued as COSV99737025; called by muse, mutect2, varscan2
- CNOT1 | c.6750C>T p.I2250= | Silent (SNP) | VAF 58/180 reads (32%) | catalogued as COSV55316518, COSV99800565; called by muse, mutect2, varscan2
- COG7 | c.2055C>T p.I685= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as rs747550560, COSV100207646; called by muse, mutect2, varscan2
- COL5A1 | c.4902C>T p.N1634= | Silent (SNP) | VAF 19/22 reads (86%) | catalogued as COSV100880125; called by muse, mutect2, varscan2
- COL6A1 | c.2712C>T p.V904= | Silent (SNP) | VAF 68/69 reads (99%) | catalogued as rs780582491, COSV100720304; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL9A2 | c.1866C>T p.I622= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs770970103, COSV101028639; ClinVar: likely benign; called by muse, mutect2, varscan2
- CPN2 | c.276C>T p.A92= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as COSV100103152; called by muse, mutect2, varscan2
- CPS1 | c.4122C>T p.F1374= | Silent (SNP) | VAF 61/118 reads (52%) | catalogued as rs1351524107, COSV99243388; called by muse, mutect2, varscan2
- CRAMP1 | c.2439C>T p.L813= | Silent (SNP) | VAF 49/132 reads (37%) | catalogued as COSV99245580; called by muse, mutect2, varscan2
- CSMD1 | c.10062C>T p.F3354= (on ENST00000520002; = p.F3353= on NM_033225.6) | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs376160512; called by muse, mutect2, varscan2
- CSMD3 | c.3909G>A p.T1303= (on ENST00000297405 / NM_001363185.1; = p.T1199= on NM_052900.3) | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as rs200793759, COSV52161031; called by muse, mutect2, varscan2
- CTRC | c.297C>T p.S99= | Silent (SNP) | VAF 38/43 reads (88%) | catalogued as rs539554130, COSV101036394; called by muse, mutect2, varscan2
- CYP2B6 | c.303C>T p.I101= | Silent (SNP) | VAF 45/98 reads (46%) | catalogued as rs766976371, COSV57844758; called by muse, mutect2, varscan2
- CYP3A7 | c.1155G>A p.G385= | Silent (SNP) | VAF 53/108 reads (49%) | catalogued as COSV100312719; called by muse, mutect2, varscan2
- CYP4X1 | c.240C>T p.F80= | Silent (SNP) | VAF 51/130 reads (39%) | catalogued as COSV64149726; called by muse, mutect2, varscan2
- DCLRE1C | c.1896G>A p.E632= (on ENST00000378278 / NM_001350965.2; = p.E517= on NM_022487.4) | Silent (SNP) | VAF 70/131 reads (53%) | catalogued as rs781144616, COSV100543064; called by muse, mutect2, varscan2
- DGLUCY | c.1020C>T p.P340= | Silent (SNP) | VAF 24/33 reads (73%) | catalogued as rs1188782460, COSV99824456; called by muse, mutect2, varscan2
- DISC1 | c.1359G>A p.T453= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as rs144844117; called by muse, mutect2, varscan2
- DNAH10 | c.11106C>T p.I3702= (on ENST00000409039; = p.I3641= on NM_207437.3) | Silent (SNP) | VAF 12/16 reads (75%) | catalogued as rs770239948, COSV68990889; called by muse, mutect2, varscan2
- DNAH3 | c.9657G>A p.E3219= | Silent (SNP) | VAF 55/144 reads (38%) | catalogued as COSV99768589; called by muse, mutect2, varscan2
- DNAH7 | c.11292C>T p.F3764= | Silent (SNP) | VAF 84/201 reads (42%) | catalogued as rs775574754, COSV56751050; called by muse, mutect2, varscan2
- DNAH7 | c.3894C>T p.S1298= | Silent (SNP) | VAF 36/78 reads (46%) | catalogued as rs1432163751, COSV100415422; called by muse, mutect2, varscan2
- DNAJC5B | c.258G>A p.L86= | Silent (SNP) | VAF 31/84 reads (37%) | catalogued as COSV99395261; called by muse, mutect2, varscan2
- DNMT3B | c.2140C>T p.L714= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV99142383; called by muse, mutect2, varscan2
- DTX2 | c.330C>T p.V110= | Silent (SNP) | VAF 56/119 reads (47%) | catalogued as rs1181948058, COSV100184696; called by muse, mutect2, varscan2
- DUOX2 | c.2442C>T p.S814= | Silent (SNP) | VAF 26/31 reads (84%) | catalogued as rs762098987, COSV101199805; called by muse, mutect2, varscan2
- DUSP16 | c.6C>T p.A2= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV99963227; called by muse, mutect2, varscan2
- EFCAB5 | c.2310C>T p.V770= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100300415; called by muse, mutect2, varscan2
- EGF | c.2634C>T p.V878= | Silent (SNP) | VAF 106/126 reads (84%) | catalogued as COSV99491118; called by muse, mutect2, varscan2
- ELOVL4 | c.573C>T p.I191= | Silent (SNP) | VAF 33/40 reads (83%) | catalogued as COSV100876182, COSV63953489; called by muse, mutect2, varscan2
- EPB41L3 | c.1974C>T p.F658= | Silent (SNP) | VAF 15/21 reads (71%) | catalogued as COSV59463711; called by muse, mutect2, varscan2
- ERI2 | c.75C>T p.L25= | Silent (SNP) | VAF 39/60 reads (65%) | catalogued as COSV99759296; called by muse, mutect2, varscan2
- ERICH3 | c.270G>A p.K90= | Silent (SNP) | VAF 70/83 reads (84%) | catalogued as COSV100444840, COSV58606832; called by mutect2, varscan2
- ESRRG | c.144C>T p.S48= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV100753320; called by muse, mutect2, varscan2
- EVA1A | c.336C>T p.F112= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV99285675; called by muse, mutect2
- F13B | c.381G>A p.G127= | Silent (SNP) | VAF 40/78 reads (51%) | catalogued as rs1281502925, COSV66375630; called by muse, mutect2, varscan2
- FAM135B | c.2484C>T p.P828= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV99425274; called by muse, mutect2, varscan2
- FAM53C | c.879C>T p.P293= | Silent (SNP) | VAF 45/102 reads (44%) | catalogued as rs200048467, COSV99524460; called by muse, mutect2, varscan2
- FBN3 | c.7437C>T p.H2479= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV99561266; called by muse, mutect2
- FBXL7 | c.381C>T p.S127= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs1161314652, COSV61648724; called by muse, mutect2, varscan2
- FBXO40 | c.423G>A p.L141= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV57522756; called by muse, mutect2, varscan2
- FCGBP | c.4173G>A p.G1391= | Silent (SNP) | VAF 77/92 reads (84%) | catalogued as rs782188289, COSV99662940; called by muse, mutect2, varscan2
- FEM1A | c.1218C>T p.F406= | Silent (SNP) | VAF 36/98 reads (37%) | catalogued as rs377569506, COSV54163169; called by muse, mutect2, varscan2
265 further variants in this file (0 protein-altering or splice-affecting, 238 silent, 27 other) are not listed here.
